Somatic mutation profile of tumor specimen C3N-00390-02 (aliquot CPT0017410009) from CPTAC case C3N-00390, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 58.2 years (21,263 days).
Specimen C3N-00390-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a71a7ce1-2a6d-4c44-bced-909ea2ac74d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00390-71 (Blood Derived Normal), aliquot CPT0017650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3519d9b-9247-453a-9c67-81b5edcd3cee

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 3, Frame Shift Del 3, Intron 3, RNA 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPAT3 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1165056438; called by muse, mutect2, varscan2
- ARHGAP19 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757936867, COSV57391247; called by muse, mutect2, varscan2
- BIRC6 | c.10798C>G p.Q3600E | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as rs1438926781; called by muse, mutect2, varscan2
- DCLRE1B | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1258661311; called by muse, mutect2, varscan2
- DSC3 | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 44/209 reads (21%) | catalogued as COSV64574524; called by muse, mutect2, varscan2
- IARS2 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs1231019285; called by muse, mutect2, varscan2
- MTMR3 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs776577601; called by muse, mutect2, varscan2
- NPAS4 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 30/189 reads (16%) | catalogued as COSV60651859; called by muse, mutect2, varscan2
- TARM1 | c.161C>T p.T54M (on ENST00000616041 / NM_001330650.1; = p.T46M on NM_001135686.3) | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs774807581, COSV101444627, COSV71524833; called by muse, mutect2, varscan2
- VHL | c.509del p.V170Afs*32 | Frame Shift Del (DEL) | VAF 84/300 reads (28%) | catalogued as rs1437199117, CM961435, CM961436, COSV56543330, COSV56555350, COSV56559921; called by mutect2, pindel, varscan2
- WDR26 | c.604T>C p.S202P (on ENST00000414423 / NM_001379403.1; = p.S102P on NM_025160.7) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV54353733; called by muse, mutect2, varscan2
- ZC3H4 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV99451692; called by muse, mutect2
- AADACL3 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AK4 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CACNA1E | c.3358_3376del p.K1120Pfs*25 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel
- CROT | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CWH43 | c.44-4_44-1delinsTAT p.X15_splice | Splice Site (DEL) | VAF 5/34 reads (15%) | called by pindel, varscan2*
- FURIN | c.1939T>C p.S647P | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GBA3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GPR68 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMY | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KDM2B | c.3196C>T p.H1066Y | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LSS | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NRP1 | c.1633A>G p.N545D | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PDE5A | c.2458T>A p.F820I | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXND1 | c.4598T>C p.I1533T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RALGAPB | c.2807G>A p.R936K | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- REV3L | c.3706G>C p.G1236R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRARP | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SRARP | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYCP2L | c.2310del p.K771Sfs*34 | Frame Shift Del (DEL) | VAF 43/213 reads (20%) | called by mutect2, pindel, varscan2
- THNSL2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ULK4 | c.1925G>C p.G642A | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- YTHDC2 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ZBED8 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF649 | c.1176T>A p.H392Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ZNF691 | c.355C>T p.Q119* (on ENST00000372502; = p.Q88* on NM_015911.3) | Nonsense Mutation (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- AC109583.1 | c.981G>A p.L327= | Silent (SNP) | VAF 35/159 reads (22%) | called by muse, mutect2, varscan2
- AIDA | c.49A>C p.R17= | Silent (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
- AIDA | c.48T>C p.F16= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs1268905608; called by muse, mutect2, varscan2
- AJAP1 | c.603C>T p.Y201= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs779289737; called by muse, mutect2, varscan2
- DYNC1LI2 | c.588G>A p.Q196= | Silent (SNP) | VAF 23/241 reads (10%) | called by muse, mutect2
- GRIA1 | c.2634G>A p.V878= | Silent (SNP) | VAF 65/389 reads (17%) | catalogued as rs772453820, COSV53589938; called by muse, mutect2, varscan2
- MUC16 | c.19986C>G p.T6662= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs538165352; called by muse, mutect2, varscan2
- MYO1H | c.366G>A p.E122= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV60450625; called by muse, mutect2, varscan2
- NLRP1 | c.2421C>A p.T807= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV52564348; called by muse, mutect2, varscan2
- TANC1 | c.1614C>T p.Y538= | Silent (SNP) | VAF 75/450 reads (17%) | catalogued as rs1432816807; called by muse, mutect2, varscan2
- ATP8B3 | c.904+113G>T | Intron (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- CAV1 | c.30+49C>A | Intron (SNP) | VAF 87/544 reads (16%) | called by muse, mutect2, varscan2
- GCNT2P1 | n.902_903del | RNA (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- OR56B3P | n.68T>C | RNA (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- SRSF7 | c.386+183G>A | Intron (SNP) | VAF 56/205 reads (27%) | catalogued as rs1173720063; called by muse, mutect2, varscan2
- ZFP36L1 | c.-95G>A | 5'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
